Somatic mutation profile of tumor specimen TARGET-30-PAPPKJ-01A (aliquot TARGET-30-PAPPKJ-01A-01W) from TARGET case TARGET-30-PAPPKJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.7 years (1,731 days).
Specimen TARGET-30-PAPPKJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0923281-644d-4779-9cf8-2c291ce8ff8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPPKJ-10A (Blood Derived Normal), aliquot TARGET-30-PAPPKJ-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4958d45e-8c03-4875-a3c8-b5e28d882120

The open-access MAF lists 251 somatic variants for this specimen: 190 protein-altering or splice-affecting, 54 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 54, Frame Shift Del 23, Nonsense Mutation 11, Splice Region 5, Intron 4, Splice Site 4, Frame Shift Ins 3, In Frame Del 3, 3'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NDUFAF1 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376344575, CM117655, COSV52975777, COSV52976616; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751711044, COSV59393589; called by muse, mutect2, varscan2
- ABCC2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV64971451; called by muse, mutect2, varscan2
- ADAMTSL5 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57861651; called by muse, mutect2, varscan2
- ADCY2 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 168/594 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV57904523; called by muse, mutect2, varscan2
- AFF4 | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 49/146 reads (34%) | catalogued as COSV54800506; called by muse, mutect2, varscan2
- AGO3 | c.2227C>T p.H743Y | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV55797821; called by muse, mutect2, varscan2
- AGPAT1 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 156/429 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV61248865; called by muse, mutect2, varscan2
- AHNAK2 | c.17117C>A p.S5706* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100315453, COSV60933457; called by muse, mutect2, varscan2
- AHR | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV54121769, COSV54126985; called by muse, mutect2, varscan2
- ALMS1 | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 170/446 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1343418024, COSV52523837; called by muse, mutect2, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- AMHR2 | c.800del p.G267Vfs*25 | Frame Shift Del (DEL) | VAF 27/120 reads (23%) | catalogued as rs748387033; called by mutect2, varscan2
- ANXA6 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV62908706; called by muse, mutect2, varscan2
- ASAP3 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60878512; called by muse, mutect2, varscan2
- ASH1L | c.971A>G p.K324R | Missense Mutation (SNP) | VAF 103/374 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV64214768; called by muse, mutect2, varscan2
- AVPR1A | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54548284; called by muse, mutect2, varscan2
- BCAS1 | c.317G>C p.R106P | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65090065; called by muse, mutect2, varscan2
- CACNA1C | c.2086C>T p.L696F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59742954; called by muse, mutect2, varscan2
- CACNG4 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 160/1090 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV50928477; called by muse, mutect2, varscan2
- CAND1 | c.2338A>T p.T780S | Missense Mutation (SNP) | VAF 99/384 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.367); catalogued as COSV73389810; called by muse, mutect2, varscan2
- CCDC149 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 154/464 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.831); catalogued as rs368466250; called by muse, mutect2, varscan2
- CDK19 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100099120; called by muse, mutect2, varscan2
- CDYL2 | c.354del p.Y120Ifs*27 | Frame Shift Del (DEL) | VAF 99/201 reads (49%) | catalogued as COSV101629564; called by mutect2, pindel, varscan2
- CFAP221 | c.1211C>G p.A404G | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV54660672, COSV54664035; called by muse, mutect2, varscan2
- CHRDL2 | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914895629, COSV55225665; called by muse, mutect2, varscan2
- CLTC | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 53/379 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV52249643; called by muse, mutect2, varscan2
- CNGA3 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs766331925, COSV55628930; called by muse, mutect2, varscan2
- COL6A3 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV55098079; called by muse, mutect2, varscan2
- COL6A6 | c.5600C>T p.A1867V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV62030425; called by muse, mutect2, varscan2
- CROT | c.390G>A p.W130* | Nonsense Mutation (SNP) | VAF 97/364 reads (27%) | catalogued as COSV58977275; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 51/175 reads (29%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- DACT1 | c.1541G>T p.S514I | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.2); catalogued as COSV60023914; called by muse, mutect2, varscan2
- DCAF12L1 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV64422925; called by muse, mutect2, varscan2
- DDX42 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771647604; called by muse, mutect2, varscan2
- DDX5 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV56751697; called by muse, mutect2, varscan2
- DDX60 | c.2437T>C p.Y813H | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67099740; called by muse, mutect2, varscan2
- DGLUCY | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV56370821; called by muse, mutect2, varscan2
- DLL1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs760667823, COSV64539041; called by muse, mutect2, varscan2
- DNTTIP1 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.057); catalogued as COSV54755677; called by muse, mutect2, varscan2
- DSC2 | c.2482A>T p.S828C | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV51870226; called by mutect2, varscan2
- DTX4 | c.1391G>A p.C464Y | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778157087, COSV57096253; called by muse, mutect2, varscan2
- DYRK4 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 33/121 reads (27%) | catalogued as COSV50542600, COSV50546700; called by muse, mutect2, varscan2
- FAM83C | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.183); catalogued as COSV65583271, COSV65584785; called by muse, mutect2, varscan2
- FEM1A | c.1495C>A p.L499I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV54165108; called by muse, mutect2, varscan2
- FFAR4 | c.696+2T>C p.X232_splice | Splice Site (SNP) | VAF 102/288 reads (35%) | catalogued as COSV65179973; called by muse, mutect2, varscan2
- FNDC1 | c.1115A>T p.N372I | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV51949257; called by muse, mutect2, varscan2
- FREM2 | c.4155G>T p.L1385F | Missense Mutation (SNP) | VAF 157/276 reads (57%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54855175; called by muse, mutect2, varscan2
- GCC1 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs934844758, COSV58463937; called by muse, mutect2, varscan2
- GCN1 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV56111549; called by muse, mutect2, varscan2
- GID4 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52010548; called by muse, mutect2, varscan2
- GIT2 | c.762C>T p.D254= | Splice Region (SNP) | VAF 22/137 reads (16%) | catalogued as COSV58085853; called by muse, mutect2, varscan2
- GNPDA2 | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766367173, COSV54948809; called by muse, mutect2, varscan2
- H1-3 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV55098753; called by muse, mutect2, varscan2
- HRNR | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 175/569 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs370041563, COSV64257495; called by muse, mutect2, varscan2
- HS3ST1 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.323); catalogued as rs202015819; called by muse, mutect2, varscan2
- HSP90AB1 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1298276030, COSV51488868; called by muse, varscan2
- IBTK | c.106T>C p.F36L | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60396738; called by muse, mutect2, varscan2
- IHH | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV55394166; called by muse, mutect2, varscan2
- IL2RG | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 119/156 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52150465; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 35/145 reads (24%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- INSYN1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV65838057; called by muse, mutect2
- ITGA5 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs373708305; called by muse, mutect2, varscan2
- ITGAM | c.1441del p.H481Ifs*45 (on ENST00000648685 / NM_001145808.2; = p.H481Ifs*44 on NM_000632.4) | Frame Shift Del (DEL) | VAF 277/855 reads (32%) | catalogued as rs1303173835; called by mutect2, pindel, varscan2
- ITPRIPL2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1276064653; called by muse, mutect2
- JAKMIP3 | c.1307T>A p.F436Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1403531311, COSV53830329; called by mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 99/313 reads (32%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KIAA1586 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV66057547; called by muse, mutect2, varscan2
- KIF21B | c.1493T>C p.M498T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV59768197; called by muse, mutect2, varscan2
- KPNB1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs986125215, COSV51601145; called by muse, mutect2, varscan2
- LRRC8E | c.676_678del p.K226del | In Frame Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs753458909; called by pindel, varscan2
- LSR | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 250/714 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV61556037; called by muse, mutect2, varscan2
- LUC7L2 | c.1001G>T p.R334I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV54930895; called by muse, mutect2, varscan2
- MACROH2A2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100952319, COSV64713954; called by muse, mutect2, varscan2
- MAFK | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52476246; called by muse, mutect2
- MAPKAPK2 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1553432606, COSV54319032; called by muse, mutect2, varscan2
- MASTL | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV60912949; called by muse, mutect2, varscan2
- MFSD9 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as COSV51496092; called by muse, mutect2, varscan2
- MINDY1 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 132/435 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.401); catalogued as COSV56501436; called by muse, mutect2, varscan2
- MIOS | c.1773G>A p.M591I | Missense Mutation (SNP) | VAF 163/653 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as COSV60770939; called by muse, mutect2, varscan2
- MIP | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745742587, COSV57789043; called by muse, mutect2, varscan2
- MLEC | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV57330566; called by muse, mutect2, varscan2
- MLLT3 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV63499453; called by muse, mutect2, varscan2
- MUC16 | c.30868G>A p.A10290T | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as COSV67447038, COSV67499970; called by muse, mutect2, varscan2
- MYBPC2 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439007318, COSV63099333; called by muse, mutect2, varscan2
- MYH3 | c.4801G>A p.A1601T | Missense Mutation (SNP) | VAF 113/1125 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs764578014, COSV56860342; called by muse, mutect2, varscan2
- NCAPD2 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as COSV57522298; called by muse, mutect2, varscan2
- NCR3 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53002647; called by muse, mutect2, varscan2
- NFKBIZ | c.1865A>G p.E622G | Missense Mutation (SNP) | VAF 128/500 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58202254; called by muse, mutect2, varscan2
- NOTCH1 | c.6566G>A p.C2189Y | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV53070465; called by muse, mutect2, varscan2
- OCLN | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 135/473 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV62285836; called by muse, mutect2, varscan2
- OGT | c.2838G>A p.M946I | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV65482912; called by muse, mutect2, varscan2
- OR10S1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV73343078; called by muse, mutect2, varscan2
- OR11H12 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV73543914; called by muse, mutect2, varscan2
- OR5H15 | c.67T>G p.W23G | Missense Mutation (SNP) | VAF 125/587 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV62949286; called by muse, mutect2, varscan2
- OR6B1 | c.426C>A p.F142L | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68770692; called by muse, mutect2, varscan2
- OTUD7A | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs200755213, COSV61044267; called by muse, mutect2, varscan2
- PACS1 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV57700370; called by muse, mutect2, varscan2
- PCARE | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 32/199 reads (16%) | catalogued as COSV59055328, COSV59058799; called by muse, mutect2, varscan2
- PCDH17 | c.457del p.L153Sfs*61 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs1185384670, COSV64974313; called by mutect2, pindel, varscan2
- PCDH8 | c.3097C>T p.L1033F | Missense Mutation (SNP) | VAF 111/486 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs1427069995, COSV58815372; called by muse, mutect2, varscan2
- PCDHA6 | c.1919C>A p.A640E | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); catalogued as COSV65348214, COSV65348221; called by muse, mutect2, varscan2
- PDCD1LG2 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 63/87 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67205048; called by muse, mutect2, varscan2
- PDZD2 | c.7036G>A p.A2346T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56875350; called by muse, mutect2, varscan2
- PDZRN4 | c.2278C>A p.L760I (on ENST00000402685 / NM_001164595.2; = p.L502I on NM_013377.4) | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54219769; called by muse, mutect2, varscan2
- PEAK1 | c.2438C>T p.T813M | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs371661687, COSV56941697; called by muse, mutect2, varscan2
- PIK3C2B | c.3740del p.G1247Vfs*35 | Frame Shift Del (DEL) | VAF 98/405 reads (24%) | catalogued as rs762818486; called by mutect2, pindel, varscan2
- PIK3R6 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61006523; called by muse, mutect2, varscan2
- PKDREJ | c.2642G>A p.C881Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53553849; called by muse, mutect2, varscan2
- PKHD1L1 | c.2363G>T p.W788L | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV65743628; called by muse, mutect2, varscan2
- PLK4 | c.1650del p.H550Qfs*6 | Frame Shift Del (DEL) | VAF 37/117 reads (32%) | catalogued as COSV54638442; called by mutect2, pindel, varscan2
- PNPLA7 | c.3082-1G>T p.X1028_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV53008184; called by muse, mutect2
- POLR2B | c.1097+2T>C p.X366_splice | Splice Site (SNP) | VAF 55/135 reads (41%) | catalogued as COSV58901836; called by muse, mutect2, varscan2
- PPARD | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as rs758636974, COSV61101776; called by muse, mutect2, varscan2
- PRDM4 | c.2198A>G p.E733G | Missense Mutation (SNP) | VAF 168/531 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57307522, COSV57307968; called by muse, mutect2, varscan2
- PTPN12 | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV50374133; called by muse, mutect2, varscan2
- RAD54B | c.322del p.E108Kfs*2 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as COSV100279638, COSV60252974; called by mutect2, pindel, varscan2
- RIOK2 | c.1306G>T p.G436* | Nonsense Mutation (SNP) | VAF 112/427 reads (26%) | catalogued as COSV51615431; called by muse, mutect2, varscan2
- ROBO4 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV60628585; called by muse, mutect2, varscan2
- SEZ6L2 | c.1245del p.V416* (on ENST00000308713 / NM_001114099.3; = p.V346* on NM_012410.4) | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as rs1567419674; called by mutect2, pindel, varscan2
- SLC22A18 | c.743T>A p.V248E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV56542438; called by muse, mutect2, varscan2
- SLC23A3 | c.1609C>A p.Q537K (on ENST00000409878 / NM_001144889.2; = p.Q420K on NM_144712.5) | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55409940; called by muse, mutect2, varscan2
- SLC25A15 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV58558426; called by muse, mutect2, varscan2
- SLC26A9 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV61603396, COSV61604191; called by muse, mutect2, varscan2
- SLC5A8 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73311286; called by muse, mutect2, varscan2
- SPZ1 | c.654del p.V219Sfs*23 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs537342243; called by mutect2, varscan2
- STARD8 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.47); PolyPhen benign (0.317); catalogued as rs149322857, COSV52932202; called by muse, mutect2, varscan2
- STAT4 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs751076320, COSV61828327; called by muse, mutect2, varscan2
- STK32C | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387515589, COSV53846850; called by muse, mutect2, varscan2
- STOML3 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 99/460 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs533210440, COSV65510570; called by muse, mutect2, varscan2
- SYNE1 | c.8673G>T p.E2891D (on ENST00000367255 / NM_182961.4; = p.E2898D on NM_033071.3) | Missense Mutation (SNP) | VAF 246/920 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as COSV55124655; called by muse, mutect2, varscan2
- SYNE2 | c.11868G>T p.L3956F | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs768272629, COSV59973259; called by muse, mutect2, varscan2
- TCHH | c.1869G>T p.E623D | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV64274132, COSV64278223; called by muse, mutect2, varscan2
- TCTN1 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as rs199525130, COSV100885968, COSV100886243; called by mutect2, varscan2
- TECPR2 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63974812; called by muse, mutect2, varscan2
- TGFBI | c.1502del p.P501Qfs*9 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs771515402; called by mutect2, pindel
- TIGD3 | c.22_24del p.K8del | In Frame Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs773003096; called by pindel, varscan2
- TMC1 | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 97/312 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM020521, CM070292, COSV52773373, COSV52786840; called by muse, mutect2, varscan2
- TNN | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs144603425; called by muse, mutect2, varscan2
- TNN | c.2715G>T p.W905C | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53437044, COSV53437562; called by muse, mutect2, varscan2
- TOGARAM2 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV65424285; called by muse, mutect2, varscan2
- TRAM2 | c.470+1G>A p.X157_splice | Splice Site (SNP) | VAF 36/106 reads (34%) | catalogued as rs1258987084, COSV51735141; called by muse, mutect2, varscan2
- TRIM42 | c.2085G>A p.K695= | Splice Region (SNP) | VAF 122/495 reads (25%) | catalogued as COSV53887532; called by muse, mutect2, varscan2
- TRPC3 | c.2756G>T p.R919I (on ENST00000379645 / NM_001366479.2; = p.R846I on NM_003305.2) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV53382658, COSV99312391; called by muse, mutect2, varscan2
- TSG101 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 439/1497 reads (29%) | catalogued as COSV52653347; called by muse, mutect2, varscan2
- TSGA10IP | c.585del p.S196Vfs*34 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs767478344; called by mutect2, pindel, varscan2
- TTN | c.58266G>A p.E19422= (on ENST00000591111; = p.E11998= on NM_003319.4) | Splice Region (SNP) | VAF 16/42 reads (38%) | catalogued as COSV60398386; called by muse, mutect2, varscan2
- TTN | c.23585A>G p.D7862G (on ENST00000591111; = p.D6935G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | PolyPhen possibly damaging (0.889); catalogued as COSV60398419; called by muse, mutect2, varscan2
- TUBGCP6 | c.5180C>T p.T1727M | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1000113726, COSV50597087; called by muse, mutect2, varscan2
- TWNK | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV52972712, COSV99272645; called by muse, mutect2, varscan2
- UBA6 | c.1860G>T p.E620D | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV59181454; called by muse, mutect2, varscan2
- VPS16 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV66799862; called by muse, mutect2, varscan2
- XDH | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 107/666 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1172296262, COSV65148877; called by muse, mutect2, varscan2
- ZC3HC1 | c.1233G>A p.S411= | Splice Region (SNP) | VAF 46/235 reads (20%) | catalogued as rs760152931, COSV61300594; called by muse, mutect2, varscan2
- ZNF429 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs773661480, COSV61919653; called by muse, mutect2, varscan2
- ZNF560 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56872391; called by muse, mutect2, varscan2
- ZNF804B | c.1628C>G p.P543R | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV60858140, COSV60859936; called by muse, mutect2, varscan2
- ZNF99 | c.1382C>A p.A461D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68055646, COSV68057222; called by muse, mutect2, varscan2
- ZP4 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV63913753; called by muse, mutect2, varscan2
- ACACA | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); called by muse, varscan2
- CACNA1G | c.679A>T p.I227F | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC38 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CLCN3 | c.1696del p.A566Lfs*18 | Frame Shift Del (DEL) | VAF 65/197 reads (33%) | called by mutect2, pindel, varscan2
- CNST | c.354dup p.G119Rfs*4 | Frame Shift Ins (INS) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- COG3 | c.2180G>A p.S727N | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- DENND5A | c.728A>T p.Y243F | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2
- DNAH17 | c.8126C>T p.T2709I | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.062); called by muse, mutect2
- DNAH8 | c.6550del p.S2184Lfs*8 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | called by mutect2, pindel, varscan2
- FBXL2 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- INSYN1 | c.741C>A p.S247R | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.134); called by muse, mutect2
- KCNA5 | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- NFKB2 | c.2686del p.Q896Sfs*41 (on ENST00000369966 / NM_001322935.1; = p.Q895Sfs*41 on NM_002502.6) | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- NRN1 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2
- PCDHB8 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFAS | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLCE1 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 19/553 reads (3%) | called by muse, mutect2
- RAB3IP | c.1182dup p.C395Mfs*8 (on ENST00000550536 / NM_175623.4; = p.C379Mfs*8 on NM_022456.5) | Frame Shift Ins (INS) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- SLC27A1 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- SLC8A1 | c.2381del p.P794Lfs*17 | Frame Shift Del (DEL) | VAF 80/457 reads (18%) | called by mutect2, pindel, varscan2
- SNRNP200 | c.2914T>C p.Y972H | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- SPTB | c.2599_2601del p.K867del | In Frame Del (DEL) | VAF 24/89 reads (27%) | called by mutect2, pindel, varscan2
- TATDN1 | c.512del p.G171Efs*16 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- TMPRSS11F | c.596C>A p.A199E | Missense Mutation (SNP) | VAF 13/374 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2
- TNS3 | c.1961del p.P654Lfs*22 | Frame Shift Del (DEL) | VAF 53/226 reads (23%) | called by mutect2, pindel, varscan2
- TRAV1-1 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP33 | c.2309-3del | Splice Region (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- USP42 | c.3707dup p.K1237Efs*16 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- ZNF235 | c.253A>C p.N85H | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- ZNF358 | c.394del p.Q132Rfs*35 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- ZNF44 | c.766del p.W256Gfs*34 (on ENST00000356109 / NM_001164276.2; = p.W208Gfs*34 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 40/92 reads (43%) | called by mutect2, pindel, varscan2
- ABCA13 | c.14520C>A p.L4840= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as rs1437804013, COSV68951368; called by muse, mutect2, varscan2
- AC098582.1 | c.99C>T p.D33= | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as COSV52025899; called by muse, mutect2, varscan2
- ACTRT2 | c.927C>T p.H309= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs762908845, COSV65760724; called by muse, mutect2, varscan2
- ADAMTS2 | c.2841C>T p.H947= | Silent (SNP) | VAF 92/352 reads (26%) | catalogued as rs779661341, COSV52397107; ClinVar: likely benign; called by muse, varscan2
- AHCTF1 | c.636C>T p.C212= (on ENST00000366508; = p.C186= on NM_015446.5) | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV100402960; called by muse, mutect2
- ALS2 | c.4152C>A p.G1384= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as COSV51893808; called by muse, mutect2, varscan2
- ATP8B1 | c.2544G>A p.Q848= | Silent (SNP) | VAF 104/310 reads (34%) | catalogued as COSV52180671; called by muse, mutect2, varscan2
- CDC42BPB | c.3207C>T p.D1069= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs140416985, COSV63475289; called by muse, mutect2
- CDC6 | c.633C>T p.C211= | Silent (SNP) | VAF 80/273 reads (29%) | catalogued as COSV52931682; called by muse, mutect2, varscan2
- CDH5 | c.960G>A p.K320= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as COSV58520398; called by muse, mutect2, varscan2
- CHRM5 | c.1224A>G p.P408= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV67248868; called by muse, mutect2, varscan2
- CNTNAP1 | c.1731C>T p.H577= | Silent (SNP) | VAF 26/222 reads (12%) | catalogued as COSV52855035; called by muse, mutect2, varscan2
- CRB1 | c.483C>T p.A161= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs370907719; called by muse, mutect2, varscan2
- CSMD2 | c.9441C>A p.G3147= | Silent (SNP) | VAF 124/271 reads (46%) | catalogued as COSV53971519; called by muse, mutect2, varscan2
- DCTN1 | c.2778G>A p.L926= | Silent (SNP) | VAF 102/290 reads (35%) | catalogued as COSV62621679; called by muse, varscan2
- DNAH17 | c.12828C>T p.D4276= | Silent (SNP) | VAF 30/254 reads (12%) | catalogued as rs773099524, COSV53149168; called by muse, mutect2, varscan2
- EEF2K | c.891C>T p.D297= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as rs201261698, COSV53779268; called by muse, mutect2, varscan2
- FAT3 | c.10011C>T p.N3337= | Silent (SNP) | VAF 29/35 reads (83%) | catalogued as COSV53184330; called by muse, mutect2, varscan2
- FLNC | c.1170T>C p.N390= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs200675882, COSV57966754; called by muse, mutect2, varscan2
- FNDC3B | c.1065G>A p.V355= | Silent (SNP) | VAF 106/383 reads (28%) | catalogued as rs781755635, COSV61051020; called by muse, mutect2, varscan2
- FNDC4 | c.675G>A p.K225= | Silent (SNP) | VAF 160/821 reads (19%) | catalogued as rs781513400, COSV53022710; called by muse, mutect2, varscan2
- GBP1 | c.1059G>T p.L353= | Silent (SNP) | VAF 52/163 reads (32%) | catalogued as COSV65084690; called by muse, mutect2, varscan2
- GRHL2 | c.888C>T p.V296= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV52556055; called by muse, mutect2, varscan2
- GRIK2 | c.1089T>A p.I363= | Silent (SNP) | VAF 48/175 reads (27%) | catalogued as COSV59778389; called by muse, mutect2, varscan2
- HNF1A | c.1692C>T p.T564= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1182421375, COSV56568764; called by muse, mutect2, varscan2
- IQCN | c.2394G>A p.K798= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs1367931127, COSV66578799; called by muse, mutect2, varscan2
- ITPKB | c.978G>A p.P326= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs1159881625, COSV55271119; called by muse, mutect2, varscan2
- KCNT1 | c.1389C>A p.A463= (on ENST00000488444; = p.A482= on NM_020822.3) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53712612, COSV99706631; called by muse, mutect2, varscan2
- KPNA5 | c.489C>A p.T163= | Silent (SNP) | VAF 59/247 reads (24%) | catalogued as COSV62655093; called by muse, mutect2, varscan2
- LPIN1 | c.978C>T p.V326= | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as rs746688689, COSV56764575; called by muse, mutect2, varscan2
- MAP1B | c.6513C>T p.S2171= | Silent (SNP) | VAF 90/340 reads (26%) | catalogued as rs1444837114, COSV57107564; called by muse, mutect2, varscan2
- MYOM2 | c.1239C>T p.P413= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs148189071, COSV100037510; called by muse, mutect2, varscan2
- NEK8 | c.1423C>T p.L475= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV52049321; called by muse, mutect2, varscan2
- NPTX1 | c.912T>C p.P304= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- NUGGC | c.36G>A p.P12= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs1211748089, COSV58432563; called by muse, mutect2, varscan2
- OR10K1 | c.285G>T p.L95= | Silent (SNP) | VAF 42/1327 reads (3%) | called by muse, mutect2
- OR9Q1 | c.267G>A p.G89= | Silent (SNP) | VAF 128/327 reads (39%) | catalogued as COSV59048553; called by muse, mutect2, varscan2
- PCARE | c.1284C>T p.D428= | Silent (SNP) | VAF 55/286 reads (19%) | catalogued as rs762494567, COSV59058791; called by muse, mutect2, varscan2
- PCDHB12 | c.1899C>T p.R633= | Silent (SNP) | VAF 28/209 reads (13%) | catalogued as COSV99506660; called by muse, mutect2, varscan2
- PCDHB13 | c.1647G>T p.V549= | Silent (SNP) | VAF 57/223 reads (26%) | catalogued as COSV53401785; called by muse, mutect2, varscan2
- PCDHB8 | c.1575G>A p.L525= | Silent (SNP) | VAF 57/540 reads (11%) | called by muse, mutect2
- PLCZ1 | c.1386T>C p.H462= | Silent (SNP) | VAF 75/259 reads (29%) | catalogued as COSV56859719; called by muse, mutect2, varscan2
- PLXNA2 | c.3480G>A p.S1160= | Silent (SNP) | VAF 59/252 reads (23%) | catalogued as rs753774411, COSV65441291; called by muse, mutect2, varscan2
- PRRC2A | c.246C>T p.D82= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV63225105; called by muse, mutect2, varscan2
- PTPRG | c.2052G>A p.Q684= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs997571527, COSV55665646; called by muse, mutect2, varscan2
- RIN3 | c.606C>T p.P202= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs769023956, COSV53648192; called by muse, mutect2, varscan2
- SIGLEC10 | c.324G>A p.A108= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as rs754120406, COSV59487322; called by muse, mutect2, varscan2
- SLIT2 | c.1308C>T p.C436= | Silent (SNP) | VAF 127/346 reads (37%) | catalogued as COSV56598687; called by muse, mutect2, varscan2
- SOST | c.258C>A p.T86= | Silent (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- SYNE1 | c.19800C>T p.D6600= (on ENST00000367255 / NM_182961.4; = p.D6529= on NM_033071.3) | Silent (SNP) | VAF 99/336 reads (29%) | catalogued as COSV55124595; called by muse, mutect2, varscan2
- SYNE1 | c.12171G>A p.P4057= (on ENST00000367255 / NM_182961.4; = p.P3986= on NM_033071.3) | Silent (SNP) | VAF 95/297 reads (32%) | catalogued as rs112128801, COSV55124625; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.102420C>T p.G34140= (on ENST00000591111; = p.G26716= on NM_003319.4) | Silent (SNP) | VAF 64/166 reads (39%) | catalogued as COSV60398351; called by muse, mutect2, varscan2
- VIL1 | c.1017G>A p.S339= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs754988094, COSV50300382; called by muse, mutect2, varscan2
- ZNF551 | c.546C>A p.T182= | Silent (SNP) | VAF 85/173 reads (49%) | catalogued as COSV56595460; called by muse, mutect2, varscan2
- ADAM8 | c.*12C>T | 3'UTR (SNP) | VAF 32/71 reads (45%) | catalogued as rs950372424; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505168 del T | 5'Flank (DEL) | VAF 37/177 reads (21%) | catalogued as rs752288826; called by mutect2, pindel, varscan2
- ASIC1 | c.1297+92T>C | Intron (SNP) | VAF 29/109 reads (27%) | catalogued as COSV57320782; called by muse, mutect2, varscan2
- C12orf77 | n.520G>A | RNA (SNP) | VAF 14/80 reads (18%) | catalogued as rs760233113; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7758C>T | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs1404889670, COSV63394744; called by muse, mutect2, varscan2
- MERTK | c.2486+122G>A | Intron (SNP) | VAF 112/334 reads (34%) | catalogued as rs1461145399; called by muse, mutect2, varscan2
- PDE4DIP | c.637-7350T>C | Intron (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
